Somatic mutation profile of cancer-model specimen HCM-BROD-0195-C71-85A (3D Neurosphere, passage 7; aliquot HCM-BROD-0195-C71-85A-01D-A786-36), derived from the primary tumor of HCMI case HCM-BROD-0195-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.0 years (18,260 days).
Specimen HCM-BROD-0195-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 516395cc-6f57-4c29-9ab1-d41be6b1c8c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0195-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0195-C71-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03a7b362-714b-4e2b-9464-9ddec4cafbff

The open-access MAF lists 64 somatic variants for this specimen: 49 protein-altering or splice-affecting, 7 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 7, Intron 4, Nonsense Mutation 3, 3'UTR 2, Splice Site 1, Translation Start Site 1, In Frame Del 1, 5'Flank 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 74/74 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs137854557, CM1111787, CS992455, COSV62194445; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 128/128 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.581T>C p.L194P | Missense Mutation (SNP) | VAF 312/315 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AFP | c.1630G>A p.A544T | Missense Mutation (SNP) | VAF 144/208 reads (69%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.795); catalogued as COSV99890117; called by muse, mutect2, varscan2
- AQP10 | c.313T>G p.L105V | Missense Mutation (SNP) | VAF 32/460 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.093); catalogued as COSV61474955; called by muse, mutect2
- CT47B1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 274/696 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1465740235, COSV64890358, COSV64890667; called by muse, mutect2, varscan2
- FRAS1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs752799316; called by muse, mutect2, varscan2
- GIMAP4 | c.421T>C p.F141L | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55432541; called by muse, mutect2
- H3C12 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as rs766949103, COSV58152382; called by mutect2, varscan2
- HEPH | c.283T>C p.W95R (on ENST00000343002; = p.W149R on NM_138737.5) | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57968265; called by muse, mutect2, varscan2
- ICAM5 | c.1204C>T p.L402F | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745981138; called by muse, mutect2, varscan2
- ITIH2 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 84/84 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as rs199888149, COSV100623341; called by muse, mutect2, varscan2
- MUC2 | c.2840C>T p.S947L | Missense Mutation (SNP) | VAF 108/284 reads (38%) | SIFT tolerated (0.33); catalogued as rs542457432; called by muse, mutect2, varscan2
- NLRP11 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as rs751156777, COSV64085872; called by muse, mutect2, varscan2
- OR4S1 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 87/175 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs777534434, COSV60679707; called by muse, mutect2, varscan2
- RSPH10B2 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 48/302 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.085); catalogued as rs771720978, COSV99786244; called by mutect2, varscan2
- SIGLEC1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 79/486 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs1262490141, COSV99163892; called by muse, mutect2, varscan2
- SLCO6A1 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 114/206 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.071); catalogued as COSV65808025; called by muse, mutect2
- SRPX | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 36/312 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs919039079, COSV59437033; called by muse, mutect2, varscan2
- TNKS | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs769744588; called by muse, mutect2, varscan2
- TNNI1 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 105/167 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs372956100; called by muse, mutect2, varscan2
- TNR | c.2674G>T p.D892Y | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54878512, COSV54899480; called by muse, varscan2
- TRPV5 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 213/636 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); catalogued as rs765394613; called by muse, mutect2, varscan2
- ZNF469 | c.5701G>A p.A1901T (on ENST00000437464; = p.A1929T on NM_001367624.2) | Missense Mutation (SNP) | VAF 274/518 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0.101); catalogued as rs1249651303; called by muse, mutect2, varscan2
- AC231657.3 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 372/847 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- BTK | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 206/445 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD36 | c.231G>T p.M77I | Missense Mutation (SNP) | VAF 20/420 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2
- CLDN34 | c.236A>T p.D79V | Missense Mutation (SNP) | VAF 169/436 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CRYZL1 | c.734A>G p.K245R | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DDX56 | c.413T>C p.V138A | Missense Mutation (SNP) | VAF 107/378 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DOCK8 | c.906_950del p.N302_R317delinsK | In Frame Del (DEL) | VAF 121/509 reads (24%) | called by mutect2, pindel
- DSCAM | c.2012C>T p.A671V | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAM9A | c.111C>A p.N37K | Missense Mutation (SNP) | VAF 108/274 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.096); called by muse, varscan2
- FAT4 | c.14848A>G p.K4950E | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.275); called by muse, mutect2
- GLT6D1 | c.805T>C p.Y269H | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IRS4 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 16/472 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- MAP3K19 | c.3784A>C p.T1262P | Missense Mutation (SNP) | VAF 162/372 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCL | c.1254G>T p.E418D | Missense Mutation (SNP) | VAF 86/178 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NDRG4 | c.247G>T p.G83W (on ENST00000570248 / NM_001378344.1; = p.G115W on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NPHP4 | c.4161C>A p.Y1387* | Nonsense Mutation (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- PPEF2 | c.1437C>A p.Y479* | Nonsense Mutation (SNP) | VAF 75/118 reads (64%) | called by muse, mutect2, varscan2
- PTPRC | c.686-1G>A p.X229_splice | Splice Site (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- RETREG2 | c.1588C>G p.L530V | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2
- SCUBE3 | c.2588T>C p.M863T | Missense Mutation (SNP) | VAF 81/159 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SMC1A | c.1868A>T p.E623V | Missense Mutation (SNP) | VAF 48/467 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TRPA1 | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- VPS53 | c.688A>C p.R230= (on ENST00000571805 / NM_001366253.2; = p.R201= on NM_018289.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 29/161 reads (18%) | called by muse, mutect2, varscan2
- ZHX3 | c.937A>G p.M313V | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ZNF479 | c.668A>G p.N223S | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2
- C8A | c.573C>T p.D191= | Silent (SNP) | VAF 127/231 reads (55%) | called by muse, varscan2
- CAT | c.891C>T p.F297= | Silent (SNP) | VAF 48/96 reads (50%) | catalogued as rs373984976; called by muse, mutect2, varscan2
- KCNT1 | c.1620C>T p.N540= (on ENST00000488444; = p.N559= on NM_020822.3) | Silent (SNP) | VAF 85/190 reads (45%) | catalogued as rs1028802868; called by muse, mutect2, varscan2
- MAP7D3 | c.2403G>A p.E801= | Silent (SNP) | VAF 151/396 reads (38%) | called by muse, mutect2, varscan2
- MEGF6 | c.2715C>G p.P905= | Silent (SNP) | VAF 32/243 reads (13%) | called by muse, mutect2, varscan2
- OBSCN | c.19923C>T p.S6641= | Silent (SNP) | VAF 50/139 reads (36%) | catalogued as rs144111673; called by muse, mutect2, varscan2
- PRKACA | c.441C>T p.Y147= | Silent (SNP) | VAF 94/170 reads (55%) | catalogued as rs558688172, COSV58067130, COSV58070627; called by muse, mutect2, varscan2
- ATP11C | c.3297+166T>A | Intron (SNP) | VAF 38/89 reads (43%) | called by muse, mutect2, varscan2
- BOD1P2 | n.239C>T | RNA (SNP) | VAF 64/88 reads (73%) | catalogued as rs1163498443; called by muse, mutect2, varscan2
- GATA1 | c.*49G>C | 3'UTR (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- GULP1 | c.399+43A>G | Intron (SNP) | VAF 22/336 reads (7%) | called by muse, mutect2
- ISLR2 | chr15:74128696 C>T | 5'Flank (SNP) | VAF 39/156 reads (25%) | catalogued as rs1170874746; called by muse, mutect2, varscan2
- PHF19 | c.465+19C>T | Intron (SNP) | VAF 404/779 reads (52%) | catalogued as COSV100384269; called by muse, mutect2, varscan2
- RTN4RL2 | c.513+516C>G | Intron (SNP) | VAF 61/114 reads (54%) | called by muse, mutect2, varscan2
- TNFRSF10B | c.*790_*794del | 3'UTR (DEL) | VAF 44/162 reads (27%) | catalogued as rs1265368763; called by pindel, varscan2
